Somatic mutation profile of cancer-model specimen HCM-CSHL-0664-C18-85M (3D Organoid, passage 20; aliquot HCM-CSHL-0664-C18-85M-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0664-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 61.4 years (22,442 days).
Specimen HCM-CSHL-0664-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 20.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 676e0b3e-7824-4ccb-8f72-0f6200d7ff37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0664-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0664-C18-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3e5c547-e5a1-408b-9c79-c0b52fc18511

The open-access MAF lists 278 somatic variants for this specimen: 215 protein-altering or splice-affecting, 51 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 194, Silent 51, Nonsense Mutation 8, Frame Shift Del 6, Intron 5, 3'UTR 3, Frame Shift Ins 3, In Frame Del 2, RNA 2, 3'Flank 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 136/136 reads (100%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXL4 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 82/353 reads (23%) | catalogued as rs964532159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 372/372 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA9 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.383); catalogued as COSV60632758; called by muse, mutect2, varscan2
- ABCC3 | c.3964G>A p.V1322M | Missense Mutation (SNP) | VAF 84/344 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs142763506; called by muse, varscan2
- ACTL7B | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 143/614 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs146150612; called by muse, mutect2, varscan2
- ADORA2A | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 90/328 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs764528797; called by muse, mutect2, varscan2
- ANK2 | c.8988A>C p.E2996D | Missense Mutation (SNP) | VAF 93/191 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.513); catalogued as COSV52153754; called by mutect2, varscan2
- ATG13 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 209/546 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1442396941, COSV56317472; called by muse, mutect2, varscan2
- ATP13A1 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99365610; called by muse, mutect2, varscan2
- ATXN7L1 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 268/622 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.137); catalogued as rs1015081086; called by muse, mutect2, varscan2
- BBS2 | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 221/394 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs954885169; called by muse, mutect2, varscan2
- C18orf63 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 94/197 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs533857307; called by muse, mutect2, varscan2
- CALD1 | c.1597G>A p.G533S (on ENST00000361675 / NM_033138.4; = p.G278S on NM_004342.7) | Missense Mutation (SNP) | VAF 307/591 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs768053736; called by muse, mutect2, varscan2
- CC2D1A | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs368857635, COSV58782756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCR6 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 91/513 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs151149068; called by muse, mutect2, varscan2
- CD8A | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 256/358 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1200297621; called by muse, mutect2, varscan2
- CLEC4G | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 121/411 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1250842245; called by muse, mutect2, varscan2
- COL16A1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 101/249 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs771126348; called by muse, mutect2, varscan2
- COL7A1 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 123/457 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); catalogued as rs201557549, COSV100097637; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPXM2 | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 108/342 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1455207884, COSV53867011, COSV53869728; called by muse, mutect2, varscan2
- CSMD3 | c.8872G>T p.V2958L (on ENST00000297405 / NM_001363185.1; = p.V2789L on NM_052900.3) | Missense Mutation (SNP) | VAF 94/771 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV99839667; called by muse, mutect2, varscan2
- CUL5 | c.381del p.K127Nfs*25 | Frame Shift Del (DEL) | VAF 152/468 reads (32%) | catalogued as COSV67609527; called by mutect2, pindel, varscan2
- DAAM2 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 137/820 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs564327973, COSV99226717; called by muse, mutect2, varscan2
- DCLK1 | c.2200C>T p.R734C (on ENST00000360631 / NM_001330072.2; = p.R427C on NM_001195416.2) | Missense Mutation (SNP) | VAF 150/423 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.973); catalogued as rs745824879, COSV55184046; called by muse, mutect2, varscan2
- DEPDC1B | c.1306A>G p.S436G | Missense Mutation (SNP) | VAF 96/249 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.52); catalogued as rs768195193; called by muse, mutect2, varscan2
- DLGAP4 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 198/1284 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs762577016, COSV59422245; called by muse, varscan2
- EHD2 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 156/366 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs775528505, COSV99621841; called by muse, mutect2, varscan2
- EHMT2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 327/328 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs150258444; called by muse, mutect2, varscan2
- EIF5A2 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 113/295 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.912); catalogued as rs1219324852, COSV55542460; called by muse, mutect2, varscan2
- ESRRG | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1476998088, COSV63170974, COSV63179370; called by muse, mutect2, varscan2
- FAM124A | c.268C>T p.R90W (on ENST00000322475 / NM_001242312.2; = p.R126W on NM_145019.4) | Missense Mutation (SNP) | VAF 289/741 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs775685213, COSV54474785; called by muse, mutect2, varscan2
- FAM135A | c.710C>T p.A237V (on ENST00000370479 / NM_001351599.1; = p.A194V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 181/383 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1232670943, COSV99525885; called by muse, mutect2, varscan2
- FAM162B | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 41/226 reads (18%) | catalogued as rs1285677851; called by muse, mutect2, varscan2
- FAM47A | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 303/303 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as rs373238471; ClinVar: benign; called by muse, mutect2, varscan2
- FAM89B | c.211_237del p.A71_G79del | In Frame Del (DEL) | VAF 239/709 reads (34%) | catalogued as rs1458727275; called by mutect2, pindel, varscan2
- FCHSD2 | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 118/408 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1268529129; called by muse, mutect2, varscan2
- FES | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs764321716, COSV100183285, COSV60997644; called by muse, mutect2, varscan2
- FGF19 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 325/624 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99594276; called by muse, mutect2, varscan2
- FIZ1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 183/539 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs867469970; called by muse, mutect2, varscan2
- FTSJ3 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 58/352 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs200565432; called by muse, mutect2, varscan2
- G6PC | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 119/669 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs768385469, COSV53830027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GP1BA | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 409/410 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as rs372575136; called by muse, varscan2
- HAAO | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 324/326 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54310738; called by muse, mutect2
- HACD4 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101529970, COSV72136707; called by muse, mutect2, varscan2
- INSRR | c.2711G>C p.S904T | Missense Mutation (SNP) | VAF 132/460 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs761505447; called by muse, mutect2, varscan2
- KCNB1 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 125/1146 reads (11%) | catalogued as COSV65568337; called by muse, mutect2, varscan2
- KCND2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 261/595 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1355394284, COSV58570790; called by muse, mutect2, varscan2
- KRT31 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 508/845 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs748743219, COSV52435034; called by muse, mutect2, varscan2
- LRFN5 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 245/389 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1476091978; called by muse, mutect2, varscan2
- MCU | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs770146478, COSV64068211; called by muse, mutect2, varscan2
- MSC | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 159/1411 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100335583; called by muse, mutect2, varscan2
- MUC17 | c.11951C>G p.S3984C | Missense Mutation (SNP) | VAF 370/716 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV60296749; called by muse, mutect2, varscan2
- MYO6 | c.3544C>T p.R1182C (on ENST00000369981; = p.R1172C on NM_004999.4) | Missense Mutation (SNP) | VAF 236/525 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752568854; called by muse, mutect2, varscan2
- NELFA | c.940G>A p.G314S (on ENST00000542778; = p.G303S on NM_005663.5) | Missense Mutation (SNP) | VAF 105/233 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1209464280, COSV100373049; called by muse, mutect2, varscan2
- NPHS1 | c.2399G>A p.R800H | Missense Mutation (SNP) | VAF 127/450 reads (28%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.616); catalogued as rs146400394; called by muse, mutect2, varscan2
- NPSR1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 209/460 reads (45%) | catalogued as rs201063902, COSV62202036; called by muse, mutect2, varscan2
- NR5A1 | c.1379A>G p.Q460R | Missense Mutation (SNP) | VAF 87/162 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146454575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OLA1 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 251/344 reads (73%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs549904049, COSV99034477; called by muse, mutect2, varscan2
- OR5P3 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 282/730 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV60429326; called by mutect2, varscan2
- OTOA | c.1591G>A p.E531K (on ENST00000286149; = p.E517K on NM_144672.4) | Missense Mutation (SNP) | VAF 188/321 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs760392364; called by muse, mutect2, varscan2
- PDE1B | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 126/208 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs558733078, COSV54492626; called by muse, mutect2, varscan2
- PHF3 | c.5116A>T p.K1706* | Nonsense Mutation (SNP) | VAF 82/357 reads (23%) | catalogued as COSV100013330; called by muse, mutect2, varscan2
- PLEKHG4B | c.3805C>T p.R1269C (on ENST00000283426; = p.R1625C on NM_052909.5) | Missense Mutation (SNP) | VAF 221/580 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.042); catalogued as rs115163479, COSV52055777; called by muse, mutect2, varscan2
- PNMA6E | c.1627G>A p.A543T (on ENST00000445091 / NM_001367770.1; = p.A265T on NM_001351293.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 333/334 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0.199); catalogued as rs1471163759; called by muse, mutect2, varscan2
- PRKN | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 105/412 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs552077922, COSV58229750; called by muse, mutect2, varscan2
- PTCHD4 | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 122/934 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV59786302; called by muse, mutect2, varscan2
- PTH2R | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 246/491 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs553009188, COSV99782945; called by muse, mutect2, varscan2
- PTPN7 | c.889C>T p.R297W (on ENST00000495688; = p.R336W on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 302/403 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776477209; called by muse, mutect2, varscan2
- RELB | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 108/358 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.733); catalogued as rs55723886, COSV55508191; called by muse, mutect2, varscan2
- RNF5 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 118/439 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770949300; called by muse, mutect2, varscan2
- RTBDN | c.215C>T p.P72L (on ENST00000393233 / NM_001270444.1; = p.P104L on NM_031429.2) | Missense Mutation (SNP) | VAF 115/481 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs1409582576; called by muse, mutect2, varscan2
- RYR3 | c.10063C>T p.R3355W (on ENST00000389232; = p.R3356W on NM_001036.6) | Missense Mutation (SNP) | VAF 297/297 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755340876, COSV66805329; called by muse, mutect2, varscan2
- SBNO1 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 125/357 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); catalogued as rs1225016162; called by muse, mutect2, varscan2
- SCUBE2 | c.2372C>A p.T791N (on ENST00000649792 / NM_001367977.2; = p.T734N on NM_020974.3) | Missense Mutation (SNP) | VAF 223/602 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757922583; called by muse, mutect2, varscan2
- SEC11C | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 220/220 reads (100%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs753497341, COSV55312414; called by muse, mutect2, varscan2
- SEC24B | c.1193G>A p.S398N | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.679); catalogued as rs372703752; called by muse, mutect2, varscan2
- SECISBP2 | c.923T>A p.L308* | Nonsense Mutation (SNP) | VAF 162/358 reads (45%) | catalogued as COSV60529167; called by muse, mutect2, varscan2
- SIM1 | c.850+1G>A p.X284_splice | Splice Site (SNP) | VAF 173/354 reads (49%) | catalogued as COSV99492013; called by muse, mutect2, varscan2
- SLCO6A1 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 165/290 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as COSV101134332; called by muse, mutect2, varscan2
- SPAG17 | c.5053G>C p.G1685R | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100308475; called by muse, mutect2, varscan2
- SPATA18 | c.268T>A p.S90T | Missense Mutation (SNP) | VAF 107/205 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs1560583856; called by muse, mutect2, varscan2
- SPIN1 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 165/379 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV65498609; called by muse, mutect2, varscan2
- SPPL2C | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 618/852 reads (73%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1248867414, COSV61292647; called by muse, varscan2
- SYPL2 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 190/273 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200417619, COSV63995343; called by muse, mutect2, varscan2
- TAF1L | c.3213G>T p.R1071S | Missense Mutation (SNP) | VAF 201/781 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV54264064; called by muse, mutect2, varscan2
- TAGLN3 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 109/403 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99845583; called by muse, mutect2, varscan2
- TGIF2LY | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 80/86 reads (93%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as rs367841917, COSV100339616; called by muse, mutect2, varscan2
- THOP1 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 363/545 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs981153307, COSV57017969; called by muse, mutect2, varscan2
- TNFRSF4 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 118/302 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55417567; called by muse, mutect2, varscan2
- TNNT2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 140/649 reads (22%) | catalogued as COSV52663416; called by muse, mutect2
- TOGARAM2 | c.1858C>T p.R620W | Missense Mutation (SNP) | VAF 149/314 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201189267, COSV65421368; called by muse, mutect2, varscan2
- TRIM49C | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 173/575 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs780192949, COSV71510513; called by muse, mutect2, varscan2
- TRPV1 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 419/419 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs780970901; called by muse, mutect2, varscan2
- UPB1 | c.937T>A p.F313I | Missense Mutation (SNP) | VAF 97/300 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58116373; called by muse, mutect2, varscan2
- USH2A | c.9205C>T p.P3069S | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.085); catalogued as rs1428395974; called by muse, mutect2, varscan2
- XYLT1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs192917273, COSV54485773; called by muse, mutect2, varscan2
- ZCCHC13 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 372/372 reads (100%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV100272496, COSV59866426; called by muse, mutect2, varscan2
- ZNF337 | c.1823G>C p.G608A | Missense Mutation (SNP) | VAF 89/526 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1412992393; called by muse, mutect2, varscan2
- ZNF433 | c.1582C>G p.H528D | Missense Mutation (SNP) | VAF 122/508 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100795031; called by muse, mutect2, varscan2
- ZNF679 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 116/254 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV55381661; called by muse, mutect2, varscan2
- ZNF91 | c.3029C>G p.T1010S | Missense Mutation (SNP) | VAF 215/342 reads (63%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.61); catalogued as rs746987256; called by muse, mutect2, varscan2
- ABCA7 | c.2110C>G p.L704V | Missense Mutation (SNP) | VAF 170/718 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- ABCA9 | c.2577A>C p.K859N | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD17B | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 68/363 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ACAN | c.2678G>T p.G893V | Missense Mutation (SNP) | VAF 325/325 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADAM8 | c.1007T>G p.M336R | Missense Mutation (SNP) | VAF 215/336 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- ADGRF5 | c.2562C>A p.S854R | Missense Mutation (SNP) | VAF 87/585 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL2 | c.1755_1756insC p.D586Rfs*8 | Frame Shift Ins (INS) | VAF 73/285 reads (26%) | called by mutect2, pindel, varscan2
- AHRR | c.756G>C p.K252N | Missense Mutation (SNP) | VAF 213/723 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- AKAP8L | c.1208A>T p.E403V | Missense Mutation (SNP) | VAF 125/359 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- AMBN | c.62T>A p.L21Q | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANGPT1 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 87/701 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ANKRD16 | c.134C>G p.A45G | Missense Mutation (SNP) | VAF 479/854 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ANKRD20A4P | c.689T>G p.M230R | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.149); called by mutect2, varscan2
- AP3B2 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 206/311 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- APBB1IP | c.1269_1270del p.Y424* | Frame Shift Del (DEL) | VAF 171/403 reads (42%) | called by pindel, varscan2
- ARPC2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 107/461 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- ASPM | c.8724G>T p.Q2908H | Missense Mutation (SNP) | VAF 136/284 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- BAP1 | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 281/431 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BFSP1 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 69/308 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CABP1 | c.608C>A p.P203Q | Missense Mutation (SNP) | VAF 256/419 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CACHD1 | c.3212A>T p.K1071I | Missense Mutation (SNP) | VAF 91/301 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CACHD1 | c.3213A>T p.K1071N | Missense Mutation (SNP) | VAF 89/299 reads (30%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CEP290 | c.7072T>G p.L2358V | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- CNOT1 | c.3229A>G p.T1077A | Missense Mutation (SNP) | VAF 172/300 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRYBG3 | c.5014del p.Q1672Kfs*14 | Frame Shift Del (DEL) | VAF 88/354 reads (25%) | called by mutect2, pindel, varscan2
- CSMD3 | c.5519T>C p.L1840P (on ENST00000297405 / NM_001363185.1; = p.L1736P on NM_052900.3) | Missense Mutation (SNP) | VAF 78/537 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CYP2C18 | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 176/176 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CYP7B1 | c.762A>T p.L254F | Missense Mutation (SNP) | VAF 67/604 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- DAZ4 | c.1007A>C p.Y336S (on ENST00000382296; = p.Y171S on NM_020420.3) | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- DHX9 | c.1098T>G p.N366K | Missense Mutation (SNP) | VAF 166/214 reads (78%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, varscan2
- DNAH8 | c.10910A>T p.K3637I | Missense Mutation (SNP) | VAF 82/382 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- DND1 | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 280/280 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- DYRK4 | c.496G>C p.V166L | Missense Mutation (SNP) | VAF 117/370 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- EIF2A | c.1692G>C p.Q564H | Missense Mutation (SNP) | VAF 139/214 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERBB2 | c.2401A>T p.M801L | Missense Mutation (SNP) | VAF 168/766 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ERG | c.663C>G p.N221K | Missense Mutation (SNP) | VAF 152/547 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ERI2 | c.1630C>G p.P544A | Missense Mutation (SNP) | VAF 31/317 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2
- FAM91A1 | c.877G>C p.G293R | Missense Mutation (SNP) | VAF 132/574 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMO1 | c.1331A>G p.N444S | Missense Mutation (SNP) | VAF 120/496 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- FSIP2 | c.2770A>G p.R924G | Missense Mutation (SNP) | VAF 155/334 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- GCNT1 | c.443A>C p.N148T | Missense Mutation (SNP) | VAF 217/474 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPAA1 | c.178_191del p.V60Cfs*29 | Frame Shift Del (DEL) | VAF 206/1172 reads (18%) | called by mutect2, pindel, varscan2
- HYDIN | c.10085T>A p.V3362D | Missense Mutation (SNP) | VAF 122/315 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- IGF1R | c.3246G>A p.M1082I | Missense Mutation (SNP) | VAF 259/259 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHG3 | c.113C>A p.T38K | Missense Mutation (SNP) | VAF 146/428 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- ITGA10 | c.2873G>A p.G958E | Missense Mutation (SNP) | VAF 86/448 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ITGA6 | c.2848G>A p.D950N (on ENST00000442250; = p.D911N on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIF4B | c.3050C>A p.S1017Y | Missense Mutation (SNP) | VAF 127/276 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- KRTAP5-5 | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 277/671 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- LRP11 | c.1258A>T p.S420C | Missense Mutation (SNP) | VAF 136/255 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- MAP2 | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 70/413 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by mutect2, varscan2
- MCM9 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- MGST3 | c.443C>G p.P148R | Missense Mutation (SNP) | VAF 295/387 reads (76%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSRB2 | c.547T>C p.*183Rext*24 | Nonstop Mutation (SNP) | VAF 467/468 reads (100%) | called by muse, mutect2, varscan2
- MUCL1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 87/287 reads (30%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2, varscan2
- NAT8 | c.612G>C p.W204C | Missense Mutation (SNP) | VAF 233/509 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- NBEA | c.3407A>C p.K1136T | Missense Mutation (SNP) | VAF 83/419 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NBEA | c.6316G>C p.D2106H | Missense Mutation (SNP) | VAF 189/327 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- NEK7 | c.257T>A p.L86H | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOX5 | c.730A>T p.T244S | Missense Mutation (SNP) | VAF 325/471 reads (69%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPVF | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 168/372 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NSD3 | c.1223dup p.S409Efs*9 | Frame Shift Ins (INS) | VAF 154/801 reads (19%) | called by mutect2, pindel, varscan2
- OR10AC1 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 92/395 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- OR10J4 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 298/447 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR2H1 | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 197/604 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OSR2 | c.36_37insT p.H13Sfs*105 | Frame Shift Ins (INS) | VAF 169/1771 reads (10%) | called by mutect2, pindel
- PCLO | c.3586G>A p.E1196K | Missense Mutation (SNP) | VAF 84/364 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PEAK3 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 382/576 reads (66%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PLEKHA7 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 298/522 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PLXNA2 | c.620_621del p.P207Rfs*9 | Frame Shift Del (DEL) | VAF 122/576 reads (21%) | called by mutect2, pindel, varscan2
- PLXNC1 | c.3576G>T p.Q1192H | Missense Mutation (SNP) | VAF 83/291 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PPIC | c.123C>G p.F41L | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRSS56 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 158/830 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PRUNE2 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 122/474 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PTPRB | c.1137A>C p.K379N | Missense Mutation (SNP) | VAF 108/301 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PTPRN | c.91G>C p.G31R | Missense Mutation (SNP) | VAF 107/329 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PTPRQ | c.4718C>T p.T1573I (on ENST00000616559; = p.T1531I on NM_001145026.2) | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAB44 | c.569T>G p.F190C | Missense Mutation (SNP) | VAF 121/731 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RALGAPA2 | c.2350G>T p.A784S | Missense Mutation (SNP) | VAF 164/376 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAPH1 | c.3713C>A p.P1238H | Missense Mutation (SNP) | VAF 87/403 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM15 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 98/352 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RELN | c.5104G>A p.V1702I | Missense Mutation (SNP) | VAF 294/590 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RIC3 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 145/657 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- RNASE11 | c.593A>C p.K198T | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- RTCB | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDF4 | c.177G>C p.K59N | Missense Mutation (SNP) | VAF 178/401 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- SH2D1A | c.244A>C p.N82H | Missense Mutation (SNP) | VAF 116/225 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH3D19 | c.1007A>C p.Q336P | Missense Mutation (SNP) | VAF 88/169 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SLC15A2 | c.1120T>G p.F374V | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SLC25A34 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCC1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 132/430 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- SNX17 | c.635A>C p.D212A | Missense Mutation (SNP) | VAF 98/383 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPAG1 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 148/686 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA31E1 | c.3493C>A p.Q1165K | Missense Mutation (SNP) | VAF 240/545 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- SPRR4 | c.113G>T p.C38F | Missense Mutation (SNP) | VAF 136/518 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SSR3 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 125/355 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SYNE1 | c.10774C>A p.Q3592K (on ENST00000367255 / NM_182961.4; = p.Q3599K on NM_033071.3) | Missense Mutation (SNP) | VAF 123/527 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SZT2 | c.8479C>G p.P2827A (on ENST00000634258 / NM_001365999.1; = p.P2770A on NM_015284.4) | Missense Mutation (SNP) | VAF 221/330 reads (67%) | SIFT tolerated (0.6); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- TCEAL8 | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TEKT3 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 135/244 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- TFDP1 | c.191T>G p.I64S | Missense Mutation (SNP) | VAF 92/520 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- TMEM132B | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 300/463 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC6A | c.99_100del p.K35Rfs*15 | Frame Shift Del (DEL) | VAF 104/285 reads (36%) | called by pindel, varscan2
- TOP3B | c.1181A>C p.K394T | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by mutect2, varscan2
- TRPT1 | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 268/446 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TXK | c.1399T>C p.F467L | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- UNC80 | c.8071G>C p.D2691H | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USF3 | c.4597_4623del p.T1533_K1541del | In Frame Del (DEL) | VAF 97/410 reads (24%) | called by mutect2, pindel, varscan2
- USH2A | c.11154T>G p.S3718R | Missense Mutation (SNP) | VAF 107/462 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13B | c.1553C>G p.T518S | Missense Mutation (SNP) | VAF 71/555 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- WWP1 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 77/782 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2
- XRCC5 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 281/281 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ZNF717 | c.2643G>C p.Q881H | Missense Mutation (SNP) | VAF 107/510 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ADCY2 | c.2982C>T p.D994= | Silent (SNP) | VAF 175/550 reads (32%) | called by muse, mutect2, varscan2
- AMIGO3 | c.318C>G p.V106= | Silent (SNP) | VAF 162/488 reads (33%) | called by muse, mutect2, varscan2
- ANKH | c.183C>T p.F61= | Silent (SNP) | VAF 281/899 reads (31%) | catalogued as COSV99414815; called by muse, mutect2, varscan2
- ANKRD20A1 | c.2883A>G p.Q961= | Silent (SNP) | VAF 18/81 reads (22%) | called by mutect2, varscan2
- ATP5F1E | c.114T>C p.T38= | Silent (SNP) | VAF 68/542 reads (13%) | catalogued as rs374383553; ClinVar: likely benign; called by muse, mutect2, varscan2
- C11orf96 | c.1008G>A p.V336= (on ENST00000339446; = p.V23= on NM_001145033.2) | Silent (SNP) | VAF 265/730 reads (36%) | called by muse, mutect2, varscan2
- CDH8 | c.1830C>T p.V610= | Silent (SNP) | VAF 32/497 reads (6%) | catalogued as rs766269925, COSV54883946; called by muse, mutect2
- CHAMP1 | c.2256C>T p.L752= | Silent (SNP) | VAF 278/493 reads (56%) | called by muse, mutect2, varscan2
- COL22A1 | c.486G>A p.A162= | Silent (SNP) | VAF 170/1238 reads (14%) | catalogued as rs781713813, COSV57330268; called by muse, varscan2
- CXCR2 | c.303G>A p.L101= | Silent (SNP) | VAF 148/684 reads (22%) | catalogued as COSV59279877; called by muse, mutect2, varscan2
- DDX56 | c.342A>T p.R114= | Silent (SNP) | VAF 87/479 reads (18%) | called by muse, mutect2, varscan2
- DNAJC14 | c.21A>G p.G7= | Silent (SNP) | VAF 63/241 reads (26%) | called by muse, mutect2, varscan2
- DOT1L | c.2301C>T p.A767= | Silent (SNP) | VAF 455/667 reads (68%) | catalogued as rs573382419; called by muse, mutect2, varscan2
- EPB41L4B | c.2451G>C p.P817= | Silent (SNP) | VAF 95/390 reads (24%) | called by muse, mutect2
- EPHB1 | c.1051C>A p.R351= | Silent (SNP) | VAF 137/396 reads (35%) | catalogued as COSV67665911; called by muse, mutect2, varscan2
- EXO1 | c.174T>C p.F58= | Silent (SNP) | VAF 140/206 reads (68%) | catalogued as COSV100799614; called by muse, mutect2, varscan2
- FUS | c.687T>C p.G229= | Silent (SNP) | VAF 198/550 reads (36%) | catalogued as rs781445592, COSV54217802; ClinVar: likely benign; called by mutect2, varscan2
- GALNT7 | c.1620C>T p.F540= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as rs781093537; called by muse, mutect2, varscan2
- GCNT7 | c.828G>A p.R276= | Silent (SNP) | VAF 115/784 reads (15%) | called by muse, mutect2, varscan2
- GLS | c.489C>G p.L163= | Silent (SNP) | VAF 60/245 reads (24%) | catalogued as rs1205775896, COSV57845317; called by muse, mutect2, varscan2
- HAT1 | c.942G>A p.V314= | Silent (SNP) | VAF 67/308 reads (22%) | catalogued as rs1026684461; called by muse, mutect2, varscan2
- HGF | c.540T>A p.P180= | Silent (SNP) | VAF 211/417 reads (51%) | called by muse, mutect2, varscan2
- IKZF1 | c.1212C>T p.N404= | Silent (SNP) | VAF 142/615 reads (23%) | catalogued as COSV58782083; called by muse, mutect2, varscan2
- KAT5 | c.1086G>A p.T362= | Silent (SNP) | VAF 293/504 reads (58%) | catalogued as rs775816226; called by muse, mutect2, varscan2
- KLF8 | c.310C>T p.L104= | Silent (SNP) | VAF 346/348 reads (99%) | catalogued as COSV63847830; called by muse, mutect2, varscan2
- LAMA4 | c.3639T>C p.N1213= (on ENST00000230538 / NM_001105206.3; = p.N1206= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 229/464 reads (49%) | called by muse, mutect2, varscan2
- MYH11 | c.4899C>T p.A1633= | Silent (SNP) | VAF 261/468 reads (56%) | catalogued as rs760584464, COSV100259841, COSV55552723; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by muse, mutect2, varscan2
- NLGN4Y | c.2187C>A p.I729= | Silent (SNP) | VAF 54/55 reads (98%) | catalogued as COSV100196868; called by muse, mutect2, varscan2
- NTN4 | c.738A>G p.Q246= | Silent (SNP) | VAF 153/434 reads (35%) | called by muse, mutect2, varscan2
- OR4Q3 | c.348A>G p.L116= | Silent (SNP) | VAF 93/454 reads (20%) | called by muse, mutect2, varscan2
- OR52N4 | c.705T>G p.A235= | Silent (SNP) | VAF 166/785 reads (21%) | called by muse, mutect2, varscan2
- PCDH8 | c.405C>T p.F135= | Silent (SNP) | VAF 134/881 reads (15%) | called by muse, mutect2, varscan2
- PKHD1 | c.9057T>A p.T3019= | Silent (SNP) | VAF 591/723 reads (82%) | called by muse, mutect2, varscan2
- PLOD2 | c.528C>G p.V176= | Silent (SNP) | VAF 49/206 reads (24%) | catalogued as rs758503433; called by muse, mutect2, varscan2
- PNMT | c.717G>A p.V239= | Silent (SNP) | VAF 132/709 reads (19%) | called by muse, mutect2, varscan2
- PRAMEF2 | c.928T>C p.L310= | Silent (SNP) | VAF 141/267 reads (53%) | catalogued as COSV53576618; called by muse, mutect2, varscan2
- PRKCB | c.1422C>T p.L474= | Silent (SNP) | VAF 178/322 reads (55%) | catalogued as rs771588066, COSV57799403; called by muse, mutect2, varscan2
- RYR2 | c.4752G>A p.P1584= | Silent (SNP) | VAF 389/505 reads (77%) | catalogued as rs780111656, COSV63658984; ClinVar: uncertain significance; called by muse, varscan2
- SHC3 | c.1494T>G p.T498= | Silent (SNP) | VAF 132/554 reads (24%) | called by muse, mutect2, varscan2
- SOX3 | c.915C>T p.A305= | Silent (SNP) | VAF 330/330 reads (100%) | catalogued as rs755200355; called by muse, varscan2
- SYNE2 | c.16563T>C p.D5521= | Silent (SNP) | VAF 104/299 reads (35%) | called by muse, mutect2, varscan2
- TDRD6 | c.168G>T p.T56= | Silent (SNP) | VAF 183/1020 reads (18%) | catalogued as COSV100288283; called by muse, mutect2, varscan2
- TLE6 | c.426G>A p.P142= (on ENST00000246112 / NM_001143986.2; = p.P19= on NM_024760.3) | Silent (SNP) | VAF 175/569 reads (31%) | catalogued as rs757907159, COSV99858315; called by muse, mutect2, varscan2
- TMEM106A | c.363G>T p.V121= | Silent (SNP) | VAF 120/689 reads (17%) | called by muse, mutect2, varscan2
- TNFAIP2 | c.1443G>C p.T481= | Silent (SNP) | VAF 64/222 reads (29%) | catalogued as rs771245667; called by muse, mutect2, varscan2
- TRIM50 | c.798C>A p.I266= | Silent (SNP) | VAF 271/535 reads (51%) | called by muse, mutect2, varscan2
- VIL1 | c.714G>C p.A238= | Silent (SNP) | VAF 494/649 reads (76%) | catalogued as rs201560572; called by muse, mutect2, varscan2
- VNN2 | c.1146C>T p.Y382= | Silent (SNP) | VAF 67/373 reads (18%) | catalogued as rs528212065; called by muse, mutect2, varscan2
- WDR64 | c.1662C>T p.L554= | Silent (SNP) | VAF 117/487 reads (24%) | called by muse, mutect2, varscan2
- XPO4 | c.3192A>G p.Q1064= | Silent (SNP) | VAF 343/585 reads (59%) | catalogued as rs1189758355; called by muse, mutect2, varscan2
- ZNF676 | c.1776C>A p.P592= (on ENST00000650058; = p.P560= on NM_001001411.3) | Silent (SNP) | VAF 93/318 reads (29%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.1200+140C>G | Intron (SNP) | VAF 104/495 reads (21%) | catalogued as COSV99770768; called by muse, mutect2, varscan2
- ATAD3B | c.*677C>T | 3'UTR (SNP) | VAF 87/435 reads (20%) | called by muse, mutect2
- CCDC158 | c.1029+3596A>G | Intron (SNP) | VAF 78/156 reads (50%) | called by muse, mutect2, varscan2
- DUSP13 | c.*308-1474C>A | Intron (SNP) | VAF 323/323 reads (100%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-32790A>C | Intron (SNP) | VAF 186/417 reads (45%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-17078del | Intron (DEL) | VAF 106/543 reads (20%) | called by mutect2, pindel, varscan2
- KCNQ2 | c.*5942G>A | 3'UTR (SNP) | VAF 153/1124 reads (14%) | catalogued as rs1327847651; called by muse, mutect2, varscan2
- LINC00960 | chr3:75678897 C>T | 3'Flank (SNP) | VAF 113/317 reads (36%) | catalogued as rs1410195668; called by muse, mutect2, varscan2
- LINP1 | n.375G>A | RNA (SNP) | VAF 567/568 reads (100%) | catalogued as rs1021600801; called by muse, mutect2, varscan2
- MAFB | c.*762C>T | 3'UTR (SNP) | VAF 117/702 reads (17%) | called by muse, mutect2, varscan2
- SREBF2 | c.-116C>T | 5'UTR (SNP) | VAF 112/274 reads (41%) | catalogued as rs1194105462; called by muse, mutect2, varscan2
- ZNF812P | n.977G>T | RNA (SNP) | VAF 87/353 reads (25%) | called by muse, mutect2, varscan2
